Gene-level copy-number profile of tumor specimen TCGA-BR-7959-01A from TCGA case TCGA-BR-7959, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mucinous adenocarcinoma; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 59.5 years (21,730 days).
Specimen TCGA-BR-7959-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.c4c020eb-2cb3-402c-934f-140f37b2bb33.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BR-7959-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/60989776-2f7d-42e6-82c5-39bde670ea3d

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 25; copy number 1: 939; copy number 2: 22,208; copy number 3: 19,821; copy number 4: 10,374; copy number 5: 3,768; copy number 6: 1,900; copy number 7: 328; copy number 8: 193; copy number 9: 30; copy number 10: 84; copy number 11: 35; copy number 12: 22; copy number 13: 45; copy number 14: 12; copy number 18: 15; copy number 20: 14.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BR-7959-01A-11D-2338-01): tumor purity 0.41, ploidy 2.84, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 24 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:11,745–197,341, 4 genes: LINC01986, AC066595.1, CHL1-AS2, AC066595.2.
- chr3:282,689–282,792, 1 gene: RNU6-1194P.
- chr3:30,606,601–31,269,406, 8 genes: TGFBR2, AC096921.1, AC096921.2, GADL1, MIR466, CNN2P6, RNA5SP127, H3P11.
- chr12:76,025,447–76,084,735, 5 genes (within-gene range 0–2): PHLDA1, AC011611.3, AC011611.4, NAP1L1, AC011611.5.
- chr16:78,825,281–79,004,730, 6 genes (within-gene range 0–1): RPS3P7, AC136603.1, AC027279.4, AC027279.1, AC027279.3, AC027279.2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 778 genes in 27 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:1,394,173–1,596,245, 2 genes, copy number 12: CRB3P1, RPL23AP38.
- chr5:16,373,361–16,465,800, 3 genes, copy number 10: LINC02150, AC020980.1, ZNF622.
- chr5:24,449,351–24,738,195, 6 genes, copy number 14 (within-gene range 13–14): Metazoa_SRP, AC010387.2, CDH10, AC091885.2, AC091885.1, AC091893.2.
- chr5:25,087,450–25,324,386, 4 genes, copy number 14 (within-gene range 5–14): LINC02228, LINC02211, AC099499.2, AC099499.1.
- chr5:30,545,177–30,743,704, 2 genes, copy number 14: AC099517.1, AC026433.1.
- chr5:31,639,131–32,110,932, 1 gene, copy number 11 (within-gene range 2–11): PDZD2.
- chr5:31,738,269–31,936,159, 13 genes, copy number 11: AC022447.5, AC022447.3, AC022447.1, AC022447.7, AC022447.6, RNU6-358P, AC010469.1, RNU6-760P, AC010469.2, RPL5P14, TPT1P5, AC025458.1, MIR4279.
- chr5:34,651,457–35,048,135, 11 genes, copy number 8: AC025754.2, RAI14, AC025754.1, AC026801.2, TTC23L, AC026801.1, RPL21P54, RAD1, BRIX1, DNAJC21, AGXT2.
- chr5:35,617,844–36,725,195, 25 genes, copy number 9 (within-gene range 6–9): SPEF2, RNU7-130P, AC137810.1, IL7R, AC112204.3, AC112204.1, CAPSL, AC112204.2, UGT3A1, UGT3A2, AC016612.1, LMBRD2, MIR580, SKP2, RNU6-1305P, NADK2, NADK2-AS1, RANBP3L, AC114277.1, RNA5SP181, AC010631.1, SLC1A3, AC008957.2, AC008957.1, AC008957.3.
- chr7:27,733,064–27,844,564, 2 genes, copy number 9 (within-gene range 3–9): TAX1BP1-AS1, TAX1BP1.
- chr8:115,408,496–121,641,440, 62 genes, copy number 7–11 (within-gene range 5–11) (broad region; genes not listed).
- chr8:121,668,934–121,697,600, 1 gene, copy number 11 (within-gene range 3–11): LINC02855.
- chr8:124,450,820–125,022,283, 18 genes, copy number 8–11: TRMT12, RNF139-AS1, RNF139, TATDN1, AC090198.1, MIR6844, NDUFB9, MTSS1, AC100858.2, MIR4662B, MIR4662A, LINC00964, MRS2P1, AC100858.1, AC100858.3, ZNF572, AC009908.1, SQLE.
- chr8:125,040,684–125,044,989, 1 gene, copy number 11: WASHC5-AS1.
- chr8:125,648,327–130,443,674, 69 genes, copy number 8–20 (within-gene range 3–20) (broad region; genes not listed).
- chr12:53,097,436–54,351,846, 87 genes, copy number 7 (broad region; genes not listed).
- chr12:56,981,211–58,244,865, 73 genes, copy number 10 (broad region; genes not listed).
- chr12:61,668,302–62,279,150, 7 genes, copy number 10: AC090629.1, TAFA2, RPL21P104, KRT8P19, RPS3P6, AC078789.1, KLF17P1.
- chr12:62,260,359–62,260,454, 1 gene, copy number 10: MIR6125.
- chr12:66,950,754–68,234,686, 20 genes, copy number 8 (within-gene range 4–8): AC073530.1, AC073530.2, RAB11AP2, GGTA2P, CAND1, AC078983.1, MRPL40P1, NTAN1P3, LINC02420, LINC02408, LINC02442, DYRK2, AC078777.1, LINC02421, AC022513.1, LINC01479, AC005294.1, IFNG-AS1, RPL39P28, HNRNPA1P70.
- chr12:69,212,108–69,610,907, 16 genes, copy number 8: AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10.
- chr12:78,052,181–78,359,746, 3 genes, copy number 9: AC073571.1, PRXL2AP1, LINC02424.
- chr12:96,194,375–98,645,113, 48 genes, copy number 7: ELK3, AC008149.1, AC008149.2, CDK17, RNU4-24P, AC125612.1, AC007513.1, RN7SKP11, CFAP54, EEF1A1P33, NEDD1, Y_RNA, AC007656.2, AC007656.1, AC007656.3, AC007656.4, LINC02409, RMST, MIR1251, AC007351.2, AC007351.3, AC007351.4, AC007351.1, AC018659.4, AC018659.3, AC018659.1, AC018659.7, AC018659.5, AC018659.8, MIR135A2, AC018659.6, AC018659.2, PAFAH1B2P2, RNU6-36P, MIR4495, MIR4303, AC016152.1, AC008055.1, RNU4-41P, AC008055.2, SLC9A7P1, LINC02453, TMPO-AS1, TMPO, PPIAP8, SLC25A3, SNORA53, IKBIP.
- chr12:103,841,451–103,930,211, 2 genes, copy number 7 (within-gene range 2–7): AC012555.1, TTC41P.
- chr12:105,019,784–105,169,130, 2 genes, copy number 8 (within-gene range 2–8): ALDH1L2, WASHC4.
- chr12:128,187,225–132,829,078, 139 genes, copy number 7–12 (within-gene range 4–12) (broad region; genes not listed).
- chr17:39,173,290–41,786,931, 160 genes, copy number 8–13 (within-gene range 4–13) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 931. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
